CPTAC case C3L-04473 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dbc7d02b-6c63-4961-a8c2-8a8b811d8d7d

Demographics
Sex at birth: female; Race: asian; Year of birth: 1951; Vital status: Dead; Days to death: 290 days; Year of death: 2019; Country of birth: India.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Age at diagnosis: 67.2 years (24,550 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 290 days; Progression or recurrence: yes; Days to recurrence: 164 days; Days to last follow up: 290 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 12; Lymph nodes tested: 18; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 290 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 164 days; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 56.3 kg; Height: 154.5 cm; BMI: 23.59.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04473-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 45 days; Initial weight: 188.9 mg; Time between excision and freezing: 43 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04473-21: Section location: Head and body; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3L-04473-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 45 days; Method of sample procurement: Blood Draw.
